Somatic mutation profile of tumor specimen MP2PRT-PAVUZL-TBP1-A (aliquot MP2PRT-PAVUZL-TBP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVUZL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,081 days).
Specimen MP2PRT-PAVUZL-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 009b2bcd-a7d7-4da6-b282-e326dcf842b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUZL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUZL-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa7e940a-8be0-405f-9ea0-394dcceca875

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMRTB1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 29/914 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1372527767; called by muse, mutect2
- ARHGEF28 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 36/724 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2
- CECR2 | c.2294C>A p.P765Q (on ENST00000342247 / NM_001290047.2; = p.P582Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 20/557 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2
- TTN | c.40980C>A p.D13660E (on ENST00000591111; = p.D6236E on NM_003319.4) | Missense Mutation (SNP) | VAF 9/189 reads (5%) | PolyPhen benign (0.015); called by muse, mutect2
- FHAD1 | c.504C>T p.S168= | Silent (SNP) | VAF 23/617 reads (4%) | catalogued as rs902832115, COSV100733569; called by muse, mutect2
- EDAR | c.655+29C>A | Intron (SNP) | VAF 31/870 reads (4%) | called by muse, mutect2
